Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A7TG, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A7TG-01A (Primary Tumor).

[page 1 of 4]
Anatomic Pathology/Cytology Document State: (version)

Update Date/Time:

Final 1

Patient Name: .

MRN:

Service Date/Time:

DOB/Age/Gender:

Male Provider:

Location: Responsible Staff:

2008-3
Oligodendroglioma, grade II
Site Brain, supratentorial NOS
path
C 71.0
C 71.1
4/22/14

DOB: (Age:) Gender: M

Client:

Taken:

Received:

Reported:

Physician(s):

Phy Location:

CLINICAL HISTORY

-old man with past history of long standing headaches and depression, and smoking, was found unresponsive at home. On CT there is a right frontal lobe slightly enhancing lesion, with thickened genu of corpus callosum and expansion of left frontal lobe.

OPERATIVE DIAGNOSES

Right frontal lesion.

Operation/Specimen: A: Brain, right frontal lobe mass, biopsy

B: Brain, right frontal lobe tumor, excision biopsy

C: Brain, right frontal lobe tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A, B, and C. Brain, right frontal, excisional biopsies and excision:

1. Oligodendroglioma (WHO II/III).

2. MIB-1 proliferation index: 2% to 4%.

See Microscopy Description and Comment.

COMMENT

The neoplasm is an oligodendroglioma devoid of nuclear anaplasia, microvascular cellular proliferation, or necrosis. There are focal proliferation centers, and zones of white matter rarefaction and gliosis. In the tissues examined the neoplasm is a WHO grade II/III. The morphology is consistent with a tumor that has 1p/19q LOH.

Electronically Signed Out

, Senior Staff Pathologist

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered:

Date Reported:

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on tissue block

(B3).

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed

[page 2 of 4]
by real-time PCR amplification of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

, Senior Staff Pathologist

Consultant:

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: Date Reported:

Interpretation

POSITIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is detected.

Informative loci are: D1S1592, D1S552, D19S219, D19S412, and PLA2G4C

Results-Comments

Testing performed on tumor paraffin block (A2) and a blood specimen

to establish germline genotype.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample

may preclude the detection of allelic loss.

PRINCIPLE: Among the major subtypes of gliomas, oligodendrogliomas are distinguished by their remarkable sensitivity to chemotherapy, with approximately 70% of anaplastic (malignant) oligodendrogliomas responding dramatically to treatment with procarbazine, lomustine, and vincristine (termed PCV) (Cairncross et al, 1998). Unfortunately, no clinical or pathologic feature allows accurate prediction of chemotherapeutic response. Oligodendrogliomas are also associated with a longer average patient survival

[page 3 of 4]
as compared to astrocytic tumors. However, the histologic distinction between oligodendroglioma and astrocytoma is often highly subjective, and there has been significant interobserver variation.

Studies (Cairncross et al, 1998; Ino et al, 2001; Smith et al, 2000) have shown that:

- allelic loss (loss of heterozygosity) of chromosome arm 1p is a statistically significant and currently the best predictor of chemosensitivity
- combined loss involving chromosome arms 1p and 19q predicts both chemotherapeutic response and longer survival in patients with oligodendrogliomas
- combined allelic loss of chromosomes 1p and 19q can be considered a molecular signature of oligodendroglioma (present in approximately 70-80% of oligodendroglial tumors and in only 10% of astrocytomas)

Electronically Signed Out

Senior Staff Pathologist

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, right frontal lobe mass, biopsy: Atypical glial proliferation consistent

with low-grade glioma. Frozen section performed at _____ and results reported to the Physician of Record.

, Senior Staff Pathologist

GROSS DESCRIPTION

A. Brain, right frontal lobe mass, biopsy: Received are 2 pieces of tan tissue, 0.8 x 0.5 x 0.4 cm. Frozen sections and smears are performed. Frozen residual is submitted in A1 and unfrozen is submitted in A2.

B. Brain, right frontal lobe tumor, excision biopsy: FIXATIVE: Formalin. NO. PIECES: 1 segment of brain tissue. SIZE/VOL: 5.0x2.5x2.1 cm. CASSETTES: 1-6,

C. Brain, right frontal lobe tumor, excision biopsy: FIXATIVE: Formalin. NO. PIECES: 1 segment of brain tissue. SIZE/VOL: 4.3x2.4x1.3 cm. CASSETTES: 1-4,

MICROSCOPIC DESCRIPTION

H\T\E: There is a neoplastic proliferation of oligodendrocytes that has some "proliferation centers", and infiltrates the brain sparsely or moderately. There are only occasional mitotic figures, more readily observed in the proliferation centers, where there is also neovascularization. There is no microvascular cellular proliferation. There is no necrosis. In part C, in addition to focal neoplasm, there is rarefaction and prominent reactive astrocytosis with Rosenthal fibers.

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates absent or sparse gliofibrillarity by the neoplastic cells. The tumor cells do not over express the p53 protein. Synaptophysin and NeuN demonstrate the proclivity of the neoplasm for the cerebral cortex, and absence of positive reaction in the neoplastic cells. The CD34 depicts the neovascularization within the tumor. With the MIB1, the overall proliferation index is about 2%, and in the proliferation centers it may be up to about 4%.

In the rarefied, gliotic areas of specimen C there are no neuronal elements, neoplastic astrocytes, or diffuse reactivity with CD34.

SPECIAL STAIN: The PAS with/without diastase fails to demonstrate granular bodies.

ICD-9(s):

[page 4 of 4]
239.6 239.6

Billing Fee Code(s):

A:

B:

C:

LOH 1p19q:

MGMT: , (More)

Histo Data

Part A: Brain, right frontal lobe mass, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

FS H/E x 1 1

H/E x 1 1

TPS H/E x 1 1

H/E x 1 2

Part B: Brain, right frontal lobe tumor, excision biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

H/E x 1 1

H/E x 1 2

mGFAP-DA x 1 3

H/E x 1 3

MGMT x 1 3 RUN LOH also. Thanks.

MIB1-DA x 1 3

P53DO7 x 1 3

H/E x 1 4

H/E x 1 5

EMA-DA x 1 6

mGFAP-DA x 1 6

H/E x 1 6

MIB1-DA x 1 6

NeuN x 1 6

Synap-DA x 1 6

Part C: Brain, right frontal lobe tumor, excision biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

mGFAP-DA x 1 1

H/E x 1 1

NeuN x 1 1

H/E x 1 2

H/E x 1 3

CD34-DA x 1 4

mGFAP-DA x 1 4

H/E x 1 4

MIB1-DA x 1 4

NeuN x 1 4

PAS x 1 4

PAS d x 1 4

Synap-DA x 1 4

*** End of Report ***

Source: NCI Genomic Data Commons file 665e6ace-0183-40fc-868d-f0f844ed4d74 (TCGA-DU-A7TG.B8C5F2FE-1618-4AB8-924E-4C2C60EF7611.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).